Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A67X, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A67X-01A (Primary Tumor).

OUS DIAGNOSIS INQUIRY

PATIENT NBR:
PAT TYPE:

PAGE #: 1
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

ear-old male with pheochromocytoma. Right adrenal pheochromocytoma. Right lap adrenalectomy.

PROCEDURE: SPGD

VERIFIED BY:

1. "Right pheochromocytoma" A 17.6 gram, 3.5 x 3.5 cm adrenal gland. Sectioning reveals a well-circumscribed 2.5 x 3.0 cm homogeneous mass arising from the medulla. The cortex is yellow and grossly unremarkable. 1A-1C. Multiple sections of the tumor with an adjacent cortex.

PROCEDURE: SPDX

VERIFIED BY:

1. Right adrenal gland, excision: Pheochromocytoma (3.0 cm in greatest dimension).

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 350c1847-8b11-442c-9e76-b33bd7670fff (TCGA-RW-A67X.D6787977-BFEC-4031-B978-0F8841376C95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).